Somatic mutation profile of tumor specimen HCM-CSHL-0258-C18-01A (aliquot HCM-CSHL-0258-C18-01A-11D-A85K-36) from HCMI case HCM-CSHL-0258-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; Age at diagnosis: 55.2 years (20,178 days).
Specimen HCM-CSHL-0258-C18-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 54240ac2-6654-4d0b-b2d2-b0efe8fd7b26.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0258-C18-10A (Blood Derived Normal), aliquot HCM-CSHL-0258-C18-10A-01D-A85K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c6474662-0add-474b-b306-3112ceee0936

The open-access MAF lists 102 somatic variants for this specimen: 73 protein-altering or splice-affecting, 27 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 59, Silent 27, Nonsense Mutation 6, In Frame Del 3, Splice Site 3, Frame Shift Del 2, 3'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA4 | c.1714C>T p.R572* | Nonsense Mutation (SNP) | VAF 102/335 reads (30%) | catalogued as rs1557787756, CM087702; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACSS3 | c.1708G>A p.A570T | Missense Mutation (SNP) | VAF 72/336 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.376); catalogued as rs763027564, COSV54094923; called by muse, mutect2, varscan2
- ATP1A4 | c.1178G>A p.R393H | Missense Mutation (SNP) | VAF 25/458 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs139315814; called by muse, mutect2
- C1QC | c.235G>A p.G79S | Missense Mutation (SNP) | VAF 181/505 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1224349185; called by muse, mutect2, varscan2
- CCDC63 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 70/279 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.799); catalogued as rs761590144, COSV57527007; called by muse, mutect2, varscan2
- COL12A1 | c.6541G>A p.D2181N | Missense Mutation (SNP) | VAF 236/466 reads (51%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs368397177; called by muse, mutect2, varscan2
- CPNE1 | c.895C>G p.P299A (on ENST00000352393; = p.P304A on NM_003915.5) | Missense Mutation (SNP) | VAF 408/677 reads (60%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); catalogued as rs758874748; called by muse, mutect2, varscan2
- CSMD3 | c.7384C>T p.R2462W (on ENST00000297405 / NM_001363185.1; = p.R2358W on NM_052900.3) | Missense Mutation (SNP) | VAF 54/242 reads (22%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.994); catalogued as rs199998952, COSV52239525; called by muse, mutect2, varscan2
- DAG1 | c.1493A>T p.E498V | Missense Mutation (SNP) | VAF 130/513 reads (25%) | SIFT tolerated (0.35); PolyPhen benign (0.063); catalogued as rs1181538352; called by muse, mutect2, varscan2
- DENND5B | c.2483C>T p.P828L | Missense Mutation (SNP) | VAF 16/183 reads (9%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs1197746420; called by muse, mutect2
- DMXL1 | c.1586G>T p.R529I | Missense Mutation (SNP) | VAF 166/220 reads (75%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as rs1401346405, COSV60710719; called by muse, mutect2, varscan2
- FAM171A2 | c.790C>T p.R264C | Missense Mutation (SNP) | VAF 43/382 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1283979758; called by muse, mutect2, varscan2
- FBN3 | c.3052G>A p.A1018T | Missense Mutation (SNP) | VAF 45/192 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.019); catalogued as rs140271593; called by muse, varscan2
- GFRAL | c.40G>T p.E14* | Nonsense Mutation (SNP) | VAF 60/211 reads (28%) | catalogued as COSV100475489; called by muse, mutect2, varscan2
- GHSR | c.265G>A p.D89N | Missense Mutation (SNP) | VAF 151/618 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53838472; called by muse, mutect2, varscan2
- GJA8 | c.287C>T p.A96V | Missense Mutation (SNP) | VAF 129/397 reads (32%) | SIFT tolerated (0.79); PolyPhen probably damaging (0.945); catalogued as COSV53788374; called by muse, mutect2, varscan2
- HK1 | c.280C>T p.R94W | Missense Mutation (SNP) | VAF 101/293 reads (34%) | SIFT tolerated (0.44); PolyPhen benign (0.009); catalogued as rs760704259; called by muse, mutect2, varscan2
- INTS1 | c.1759C>T p.R587W | Missense Mutation (SNP) | VAF 87/388 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as rs1399694238; called by muse, mutect2, varscan2
- IWS1 | c.685C>T p.P229S | Missense Mutation (SNP) | VAF 145/559 reads (26%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.005); catalogued as COSV54867780; called by muse, mutect2, varscan2
- OR4Q2 | c.773G>A p.R258H | Missense Mutation (SNP) | VAF 90/457 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as rs539242908; called by muse, mutect2, varscan2
- PCDH11X | c.265G>A p.A89T | Missense Mutation (SNP) | VAF 134/432 reads (31%) | SIFT tolerated (0.63); PolyPhen benign (0.011); catalogued as rs1321956313, COSV53446770; called by muse, mutect2, varscan2
- PCDHA8 | c.470C>T p.A157V | Missense Mutation (SNP) | VAF 127/490 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV65337661; called by muse, mutect2, varscan2
- PEG10 | c.349C>T p.R117C (on ENST00000482108 / NM_001040152.2; = p.R151C on NM_015068.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 48/618 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV101509860; called by muse, mutect2
- PIP4K2A | c.608G>A p.R203H | Missense Mutation (SNP) | VAF 55/253 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.052); catalogued as rs185148351; called by muse, mutect2
- POM121L2 | c.2683G>A p.V895M | Missense Mutation (SNP) | VAF 87/448 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.257); catalogued as rs951963533; called by muse, varscan2
- PPP2R2B | c.428C>A p.A143D (on ENST00000394409; = p.A209D on NM_181674.2) | Missense Mutation (SNP) | VAF 84/361 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.038); catalogued as rs1158087759; called by muse, varscan2
- PTPRA | c.382G>A p.A128T | Missense Mutation (SNP) | VAF 58/224 reads (26%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0); catalogued as rs1262326859; called by muse, mutect2, varscan2
- RGS3 | c.1262G>A p.R421H (on ENST00000350696 / NM_001282923.2; = p.R309H on NM_017790.4) | Missense Mutation (SNP) | VAF 174/480 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.272); catalogued as rs775749351; called by muse, mutect2, varscan2
- SLC12A8 | c.316G>A p.V106I | Missense Mutation (SNP) | VAF 138/649 reads (21%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.456); catalogued as rs775399116, COSV58863097; called by muse, mutect2, varscan2
- SLC8A3 | c.1862C>A p.P621Q | Missense Mutation (SNP) | VAF 87/330 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99385574; called by mutect2, varscan2
- SOAT1 | c.1155G>T p.L385F | Missense Mutation (SNP) | VAF 52/189 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); catalogued as rs1378236359; called by muse, mutect2, varscan2
- TMCO4 | c.560G>T p.W187L | Missense Mutation (SNP) | VAF 65/253 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as rs1477225462, COSV53877910; called by muse, mutect2, varscan2
- TTN | c.94702G>C p.A31568P (on ENST00000591111; = p.A24144P on NM_003319.4) | Missense Mutation (SNP) | VAF 123/513 reads (24%) | PolyPhen possibly damaging (0.629); catalogued as rs1244887390; called by muse, mutect2, varscan2
- ZFHX3 | c.9775_9777del p.K3259del | In Frame Del (DEL) | VAF 132/630 reads (21%) | catalogued as rs764542298; called by pindel, varscan2
- ZNF521 | c.508G>A p.G170R | Missense Mutation (SNP) | VAF 152/466 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1568023002, COSV64123636; called by muse, mutect2, varscan2
- ABHD17C | c.535T>C p.S179P | Missense Mutation (SNP) | VAF 126/337 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- ADCY9 | c.3118G>A p.V1040M | Missense Mutation (SNP) | VAF 92/345 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARSH | c.272G>T p.G91V | Missense Mutation (SNP) | VAF 34/318 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- BNC2 | c.652C>T p.R218* | Nonsense Mutation (SNP) | VAF 79/240 reads (33%) | called by muse, mutect2, varscan2
- C9orf50 | c.716+1G>A p.X239_splice | Splice Site (SNP) | VAF 73/214 reads (34%) | called by muse, mutect2, varscan2
- CALCR | c.522-3_523del p.X174_splice | Splice Site (DEL) | VAF 28/191 reads (15%) | called by mutect2, pindel, varscan2
- CRACD | c.959G>A p.R320Q | Missense Mutation (SNP) | VAF 51/494 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CRX | c.606C>A p.C202* | Nonsense Mutation (SNP) | VAF 39/544 reads (7%) | called by muse, mutect2
- DACT3 | c.632G>A p.R211H | Missense Mutation (SNP) | VAF 225/402 reads (56%) | SIFT tolerated (0.3); PolyPhen benign (0.088); called by muse, varscan2
- DDX58 | c.2362A>T p.K788* | Nonsense Mutation (SNP) | VAF 43/163 reads (26%) | called by muse, mutect2, varscan2
- DNAJA4 | c.860T>G p.V287G (on ENST00000343789; = p.V316G on NM_018602.3) | Missense Mutation (SNP) | VAF 61/209 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- FREM3 | c.743C>G p.A248G | Missense Mutation (SNP) | VAF 170/521 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- GDPD2 | c.577C>T p.L193F | Missense Mutation (SNP) | VAF 38/436 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2
- GNAT3 | c.955A>G p.I319V | Missense Mutation (SNP) | VAF 78/332 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- GOLGA8M | c.1200G>C p.E400D | Missense Mutation (SNP) | VAF 70/281 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- JUN | c.943_954del p.H315_S318del | In Frame Del (DEL) | VAF 91/347 reads (26%) | called by mutect2, pindel, varscan2
- KCNN2 | c.733T>C p.Y245H (on ENST00000264773; = p.Y457H on NM_021614.4) | Missense Mutation (SNP) | VAF 38/454 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.037); called by muse, mutect2
- KIR3DL2 | c.836A>T p.D279V | Missense Mutation (SNP) | VAF 72/305 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- KRTAP4-7 | c.166C>A p.Q56K | Missense Mutation (SNP) | VAF 57/1393 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.039); called by muse, mutect2
- PCDH11X | c.3893G>A p.G1298D | Missense Mutation (SNP) | VAF 314/519 reads (61%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PCDH15 | c.5377C>A p.P1793T | Missense Mutation (SNP) | VAF 38/350 reads (11%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.053); called by muse, mutect2
- PDZRN4 | c.2873G>A p.R958H (on ENST00000402685 / NM_001164595.2; = p.R700H on NM_013377.4) | Missense Mutation (SNP) | VAF 105/470 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- PLEKHA6 | c.2015A>G p.D672G | Missense Mutation (SNP) | VAF 62/293 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- PLEKHG7 | c.1988T>G p.I663R | Missense Mutation (SNP) | VAF 54/308 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); called by muse, mutect2, varscan2
- POPDC2 | c.296T>G p.L99R | Missense Mutation (SNP) | VAF 124/496 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- PPFIA4 | c.3422C>T p.A1141V (on ENST00000447715; = p.A1142V on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 178/588 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- PPIAL4D | c.225C>G p.D75E | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.176); called by mutect2, varscan2
- PTPN2 | c.1224_1225del p.F410Sfs*9 | Frame Shift Del (DEL) | VAF 70/280 reads (25%) | called by mutect2, pindel, varscan2
- SMARCC2 | c.494G>T p.G165V | Missense Mutation (SNP) | VAF 63/272 reads (23%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SMC2 | c.334A>G p.R112G | Missense Mutation (SNP) | VAF 55/199 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- SOX9 | c.1239_1241del p.H413_S414delinsQ | In Frame Del (DEL) | VAF 470/845 reads (56%) | called by mutect2, pindel*, varscan2
- TPO | c.655G>C p.V219L | Missense Mutation (SNP) | VAF 60/725 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.048); called by muse, mutect2
- TRPM7 | c.4060G>A p.A1354T | Missense Mutation (SNP) | VAF 66/227 reads (29%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- TTLL12 | c.1529A>C p.K510T | Missense Mutation (SNP) | VAF 62/240 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.326); called by mutect2, varscan2
- WASHC4 | c.2165T>G p.F722C | Missense Mutation (SNP) | VAF 19/363 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.871); called by muse, mutect2
- WDR48 | c.973-1G>C p.X325_splice | Splice Site (SNP) | VAF 47/198 reads (24%) | called by muse, mutect2, varscan2
- ZDHHC16 | c.402C>A p.Y134* | Nonsense Mutation (SNP) | VAF 98/304 reads (32%) | called by muse, mutect2, varscan2
- ZRANB3 | c.2297del p.L766* | Frame Shift Del (DEL) | VAF 56/274 reads (20%) | called by mutect2, pindel, varscan2
- ACMSD | c.309C>T p.T103= | Silent (SNP) | VAF 221/439 reads (50%) | catalogued as rs946527173; called by muse, mutect2, varscan2
- ADORA1 | c.453G>A p.A151= | Silent (SNP) | VAF 134/438 reads (31%) | catalogued as rs760767699, COSV55144423; called by muse, mutect2, varscan2
- AFDN | c.4098G>T p.P1366= | Silent (SNP) | VAF 38/644 reads (6%) | catalogued as COSV60051194; called by muse, mutect2
- ARHGAP35 | c.4179C>T p.S1393= | Silent (SNP) | VAF 84/379 reads (22%) | catalogued as rs201617559; called by muse, mutect2, varscan2
- ASAP1 | c.2886G>T p.L962= | Silent (SNP) | VAF 54/614 reads (9%) | called by muse, mutect2
- ASPHD1 | c.612C>T p.D204= | Silent (SNP) | VAF 107/404 reads (26%) | catalogued as COSV58097834; called by muse, mutect2, varscan2
- CDH10 | c.477G>A p.T159= | Silent (SNP) | VAF 89/402 reads (22%) | catalogued as rs559592064, COSV52580188; called by muse, mutect2, varscan2
- CNTNAP5 | c.1143C>T p.P381= | Silent (SNP) | VAF 217/496 reads (44%) | catalogued as rs769673214, COSV70477851, COSV70501264; called by muse, varscan2
- CSMD3 | c.5667A>G p.R1889= (on ENST00000297405 / NM_001363185.1; = p.R1785= on NM_052900.3) | Silent (SNP) | VAF 27/459 reads (6%) | called by muse, mutect2
- CYLC2 | c.156T>C p.S52= | Silent (SNP) | VAF 70/297 reads (24%) | called by muse, mutect2, varscan2
- ERFE | c.228C>T p.V76= | Silent (SNP) | VAF 80/338 reads (24%) | catalogued as rs1298751704, COSV60138177; called by muse, mutect2, varscan2
- GPM6A | c.474G>T p.L158= | Silent (SNP) | VAF 57/327 reads (17%) | called by muse, mutect2, varscan2
- ISM1 | c.618T>C p.F206= | Silent (SNP) | VAF 29/394 reads (7%) | called by muse, mutect2
- KCNN1 | c.354C>T p.I118= | Silent (SNP) | VAF 70/340 reads (21%) | catalogued as rs781062974, COSV55838482; called by muse, varscan2
- KLK4 | c.489C>T p.T163= | Silent (SNP) | VAF 90/378 reads (24%) | catalogued as rs748990839, COSV100133744; called by muse, mutect2, varscan2
- MID1IP1 | c.369C>T p.S123= | Silent (SNP) | VAF 415/665 reads (62%) | called by muse, mutect2, varscan2
- MTSS2 | c.1254C>T p.S418= | Silent (SNP) | VAF 83/419 reads (20%) | catalogued as rs755940702; called by muse, mutect2, varscan2
- OR2L13 | c.921C>T p.F307= | Silent (SNP) | VAF 47/199 reads (24%) | catalogued as rs1299358473, COSV63557133; called by muse, mutect2, varscan2
- PCDH17 | c.444C>A p.G148= | Silent (SNP) | VAF 155/676 reads (23%) | catalogued as rs370709004; called by muse, mutect2, varscan2
- PLEKHO1 | c.708G>C p.R236= | Silent (SNP) | VAF 15/459 reads (3%) | called by muse, mutect2
- PTPRQ | c.2838T>A p.T946= (on ENST00000616559; = p.T904= on NM_001145026.2) | Silent (SNP) | VAF 54/222 reads (24%) | called by muse, mutect2, varscan2
- SALL3 | c.1974G>A p.T658= | Silent (SNP) | VAF 207/642 reads (32%) | catalogued as rs759576604, COSV73306329; called by muse, mutect2, varscan2
- SDK1 | c.2055C>T p.A685= | Silent (SNP) | VAF 121/474 reads (26%) | catalogued as rs151044664; called by muse, mutect2, varscan2
- SH2B3 | c.690C>T p.P230= | Silent (SNP) | VAF 131/475 reads (28%) | catalogued as rs752696254; called by muse, mutect2, varscan2
- SUPT3H | c.423G>A p.A141= (on ENST00000371460 / NM_181356.3; = p.A130= on NM_003599.4 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 178/345 reads (52%) | catalogued as rs369564016; called by muse, mutect2, varscan2
- TRIB2 | c.705C>T p.A235= | Silent (SNP) | VAF 134/560 reads (24%) | catalogued as rs759295610; called by muse, mutect2, varscan2
- ZFHX2 | c.4299C>T p.N1433= | Silent (SNP) | VAF 230/478 reads (48%) | catalogued as rs1446340152; called by muse, mutect2, varscan2
- MFRP | chr11:119345618 A>C | 5'Flank (SNP) | VAF 49/205 reads (24%) | called by muse, mutect2, varscan2
- WDR64 | c.*918A>C | 3'UTR (SNP) | VAF 8/144 reads (6%) | called by muse, mutect2
